Somatic mutation profile of tumor specimen TARGET-10-PATBRV-09A (aliquot TARGET-10-PATBRV-09A-01D) from TARGET case TARGET-10-PATBRV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.4 years (3,054 days).
Specimen TARGET-10-PATBRV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a31444b-ffa7-47f0-8a77-0b4a4af55ec0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATBRV-10A (Blood Derived Normal), aliquot TARGET-10-PATBRV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5c0af33-c03b-4a09-bc62-cb66c0ffdf4e

The open-access MAF lists 40 somatic variants for this specimen: 26 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 11, Nonsense Mutation 4, Frame Shift Ins 2, Frame Shift Del 1, Intron 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARF5 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV50001268; called by mutect2, varscan2
- ATRNL1 | c.3367G>T p.E1123* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as rs1554969757, COSV58093415; called by muse, mutect2, varscan2
- CTCF | c.1339_1340insT p.A447Vfs*5 | Frame Shift Ins (INS) | VAF 46/117 reads (39%) | catalogued as COSV50474651; called by mutect2, pindel, varscan2
- ETV6 | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 15/87 reads (17%) | catalogued as COSV67150789, COSV67151946; called by muse, mutect2, varscan2
- FBN2 | c.8030A>G p.K2677R | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV52520645; called by muse, mutect2, varscan2
- FBN2 | c.1315G>A p.G439R | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.863); catalogued as rs763844373, COSV52520668; called by muse, varscan2
- FBXO40 | c.1588C>A p.Q530K | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV57524824; called by muse, mutect2, varscan2
- FOXRED2 | c.788A>G p.N263S | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53400366; called by muse, mutect2, varscan2
- GLIS3 | c.1895C>A p.S632* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as rs187615896, COSV60930732, COSV60935861; called by muse, varscan2
- GSC2 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.101); catalogued as COSV50082466; called by muse, mutect2, varscan2
- ITPR2 | c.7465G>A p.V2489M | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV67264302; called by muse, mutect2, varscan2
- KCNK18 | c.242A>G p.Q81R | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV57972118; called by muse, mutect2, varscan2
- KIF5A | c.2487G>T p.K829N | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1363391519, COSV54055698; called by muse, mutect2, varscan2
- MACF1 | c.13825G>T p.D4609Y (on ENST00000372915; = p.D2542Y on NM_012090.5) | Missense Mutation (SNP) | VAF 41/84 reads (49%) | catalogued as COSV57127061; called by muse, mutect2, varscan2
- MAGEB6 | c.732G>C p.L244F | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100983681, COSV66872455; called by muse, mutect2, varscan2
- NIPBL | c.4422G>T p.R1474S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as rs80358358, CM107663; ClinVar: uncertain significance; called by muse, varscan2
- NOTCH1 | c.7397_7398insTTAGGC p.T2466_S2467ins* | Nonsense Mutation (INS) | VAF 15/26 reads (58%) | catalogued as COSV53032287, COSV53075325; called by mutect2, pindel, varscan2
- PCDHGB6 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.603); catalogued as COSV53967265; called by muse, mutect2
- PDE6B | c.391G>A p.V131I | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs145863444; called by muse, mutect2, varscan2
- PTPRQ | c.6139C>A p.L2047I (on ENST00000616559; = p.L2014I on NM_001145026.2) | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as COSV57036121, COSV57043229; called by muse, mutect2, varscan2
- RASAL2 | c.722del p.K241Rfs*7 | Frame Shift Del (DEL) | VAF 13/105 reads (12%) | catalogued as rs771909008; called by mutect2, varscan2
- STAT5B | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as rs1449203089, COSV53180754; called by muse, mutect2, varscan2
- TLN2 | c.5556_5557insACGTGCCCATT p.D1853Tfs*19 | Frame Shift Ins (INS) | VAF 22/53 reads (42%) | catalogued as COSV60890970; called by mutect2, pindel, varscan2
- ATAD2 | c.2718G>T p.E906D | Missense Mutation (SNP) | VAF 6/131 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.17); called by muse, mutect2
- IGLC3 | c.239A>T p.K80M | Missense Mutation (SNP) | VAF 6/14 reads (43%) | PolyPhen benign (0.077); called by muse, varscan2
- ZGPAT | c.310G>A p.V104I | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- COL1A2 | c.2523C>A p.G841= | Silent (SNP) | VAF 21/34 reads (62%) | called by muse, mutect2, varscan2
- CREBL2 | c.309C>T p.N103= | Silent (SNP) | VAF 59/97 reads (61%) | called by muse, mutect2, varscan2
- GRM7 | c.1785C>A p.V595= | Silent (SNP) | VAF 26/50 reads (52%) | called by muse, mutect2
- KPNA2 | c.1285T>C p.L429= | Silent (SNP) | VAF 45/113 reads (40%) | called by muse, mutect2, varscan2
- MXRA5 | c.6936C>T p.N2312= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as rs1395608870, COSV54227919; called by muse, mutect2, varscan2
- RBCK1 | c.54A>T p.A18= | Silent (SNP) | VAF 21/42 reads (50%) | called by muse, mutect2, varscan2
- RTN4RL1 | c.438C>T p.G146= | Silent (SNP) | VAF 34/66 reads (52%) | catalogued as rs771569249; called by muse, mutect2, varscan2
- SLC25A48 | c.390G>A p.R130= | Silent (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2, varscan2
- SSTR3 | c.651G>A p.G217= | Silent (SNP) | VAF 6/9 reads (67%) | called by muse, mutect2, varscan2
- SULT1C4 | c.12C>T p.H4= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as rs144464562; called by muse, mutect2, varscan2
- ZNF30 | c.57G>A p.V19= | Silent (SNP) | VAF 42/94 reads (45%) | catalogued as COSV57852901, COSV57855319; called by muse, mutect2, varscan2
- GABBR1 | c.2218-59G>A | Intron (SNP) | VAF 35/59 reads (59%) | catalogued as rs748054962; called by muse, mutect2, varscan2
- LRRC37A16P | n.3306T>C | RNA (SNP) | VAF 17/29 reads (59%) | called by muse, mutect2, varscan2
- SATL1 | c.-1C>T | 5'UTR (SNP) | VAF 18/45 reads (40%) | catalogued as rs369947679, COSV60576754; called by muse, mutect2, varscan2
